Somatic mutation profile of tumor specimen 6319b36b-533c-4e86-8e12-80552e (aliquot 6319b36b-533c-4e86-8e12-80552e_D6) from CPTAC case 26OV002, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 6319b36b-533c-4e86-8e12-80552e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7ce743e-c95b-4b6a-85dc-5cbc3bda9db6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 70daa657-8dd1-48e7-a69b-e3d7d1 (Blood Derived Normal), aliquot 70daa657-8dd1-48e7-a69b-e3d7d1_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df2e551e-463a-405b-bead-ab4dab9fa4f0

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 4, 5'Flank 3, Intron 3, Splice Site 2, 5'UTR 2, 3'Flank 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 274/362 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 308/441 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 308/440 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV53020321, COSV53164604, COSV53577379; called by muse, mutect2, varscan2
- CCR1 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 128/162 reads (79%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs199658624, COSV56121799; called by muse, mutect2, varscan2
- CD163 | c.3140G>A p.R1047H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs142819685, COSV63134330; called by muse, mutect2, varscan2
- CNGB1 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as rs769302175; called by muse, mutect2, varscan2
- CTBP2 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs767182849, COSV58333506, COSV58334723; called by muse, mutect2
- DIP2C | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs888425993, COSV55159684; called by muse, mutect2, varscan2
- ENPP7 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs782527487, COSV100093805; called by muse, mutect2, varscan2
- MACIR | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 80/96 reads (83%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as rs189792579; called by muse, mutect2, varscan2
- MARK1 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs565080172, COSV65068257; called by muse, mutect2, varscan2
- MCM8 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 113/369 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144824405; called by muse, mutect2, varscan2
- PKHD1L1 | c.9836G>A p.R3279H | Missense Mutation (SNP) | VAF 32/381 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs763295862; called by muse, mutect2
- PLXNA3 | c.4834C>T p.R1612C | Missense Mutation (SNP) | VAF 66/90 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782446260, COSV100859927; called by muse, mutect2, varscan2
- SLC9A1 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs767640230; called by muse, mutect2, varscan2
- SNX33 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57914579; called by muse, mutect2, varscan2
- ZBTB14 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 109/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100813482; called by muse, mutect2, varscan2
- ZNF865 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.1); catalogued as rs1342146665; called by muse, mutect2, varscan2
- CRB2 | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM83B | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCMT1 | c.779C>A p.S260* | Nonsense Mutation (SNP) | VAF 83/111 reads (75%) | called by muse, mutect2, varscan2
- MYOM3 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- NT5DC1 | c.803-1G>C p.X268_splice | Splice Site (SNP) | VAF 84/108 reads (78%) | called by muse, mutect2, varscan2
- RB1 | c.1128-2_1135del p.X376_splice | Splice Site (DEL) | VAF 107/151 reads (71%) | called by mutect2, pindel, varscan2
- SARDH | c.2109C>A p.S703R | Missense Mutation (SNP) | VAF 76/133 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SEC62 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 103/130 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- STK17B | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SUPT20H | c.684G>T p.K228N (on ENST00000350612 / NM_001014286.3; = p.K229N on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TET2 | c.2354T>G p.F785C | Missense Mutation (SNP) | VAF 328/457 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TULP2 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TXNIP | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- VIT | c.952G>A p.D318N (on ENST00000389975 / NM_001177969.1; = p.D333N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF671 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 113/560 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GALNT12 | c.477C>A p.V159= | Silent (SNP) | VAF 120/602 reads (20%) | called by muse, mutect2, varscan2
- GAS7 | c.228G>A p.T76= (on ENST00000432992 / NM_201433.2; = p.T16= on NM_201432.2) | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as rs750059886; called by muse, mutect2, varscan2
- SLC22A23 | c.1290C>T p.N430= | Silent (SNP) | VAF 239/302 reads (79%) | catalogued as rs770532705; called by muse, mutect2, varscan2
- ST8SIA2 | c.186C>T p.S62= | Silent (SNP) | VAF 233/495 reads (47%) | called by muse, mutect2, varscan2
- ANKIB1 | c.1085+2915T>G | Intron (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- BAZ1A | chr14:34875500 A>T | 5'Flank (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- DOHH | c.-2C>T | 5'UTR (SNP) | VAF 23/73 reads (32%) | catalogued as rs766450742; called by muse, mutect2, varscan2
- ENPEP | c.1509+410C>T | Intron (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- JKAMP | c.-1A>G | 5'UTR (SNP) | VAF 102/185 reads (55%) | called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407719 A>G | 5'Flank (SNP) | VAF 239/464 reads (52%) | called by muse, mutect2, varscan2
- NGRN | chr15:90275627 A>T | 3'Flank (SNP) | VAF 182/291 reads (63%) | called by muse, mutect2, varscan2
- OSR2 | c.756+84_756+87del | Intron (DEL) | VAF 243/424 reads (57%) | catalogued as rs764215600; called by mutect2, pindel, varscan2
- RASA4CP | chr7:44039621 C>G | 5'Flank (SNP) | VAF 134/722 reads (19%) | called by muse, mutect2
- VAPB | c.*2124T>G | 3'UTR (SNP) | VAF 125/376 reads (33%) | called by muse, mutect2, varscan2
